Somatic mutation profile of tumor specimen ALCH-AEZK-TTP1-A (aliquot ALCH-AEZK-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AEZK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 62.4 years (22,795 days).
Specimen ALCH-AEZK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 482a983c-1b60-4adc-ae62-2ae64c368661.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEZK-NB1-A (Blood Derived Normal), aliquot ALCH-AEZK-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/459cf05c-fb91-4e2c-96ab-9eebbc369f16

The open-access MAF lists 399 somatic variants for this specimen: 254 protein-altering or splice-affecting, 84 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 84, Intron 28, Nonsense Mutation 23, RNA 13, Frame Shift Del 10, 3'UTR 8, Splice Region 6, 5'Flank 6, 5'UTR 4, Splice Site 4, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TANGO2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as rs1162037663; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 70/354 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TTN | c.45738C>A p.Y15246* (on ENST00000591111; = p.Y7822* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 103/556 reads (19%) | catalogued as rs1553696233; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY9 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV53573964; called by muse, mutect2, varscan2
- AHSG | c.303C>G p.S101R | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99890001; called by muse, mutect2, varscan2
- ALPK1 | c.2683A>T p.N895Y | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.122); catalogued as COSV51589517; called by muse, mutect2, varscan2
- ARSK | c.778A>T p.T260S | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs998682024; called by muse, mutect2, varscan2
- BPIFB3 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 44/189 reads (23%) | catalogued as COSV64957462; called by muse, mutect2, varscan2
- BSND | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780910610, COSV64870300; called by muse, mutect2, varscan2
- CCDC141 | c.2815G>A p.A939T | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs1244958227; called by muse, mutect2, varscan2
- CFHR4 | c.1654G>T p.G552* (on ENST00000367416 / NM_001201551.2; = p.G306* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 71/414 reads (17%) | catalogued as COSV99260428; called by muse, mutect2, varscan2
- COL11A1 | c.1943C>A p.A648D | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs778758741; called by muse, mutect2, varscan2
- COL11A1 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 88/539 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV62188952; called by muse, mutect2, varscan2
- COMMD2 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 122/712 reads (17%) | catalogued as rs763900101; called by muse, mutect2, varscan2
- CPEB3 | c.1165+1G>T p.X389_splice | Splice Site (SNP) | VAF 26/105 reads (25%) | catalogued as rs1391087552; called by muse, varscan2
- CXCR1 | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | catalogued as COSV99826263; called by muse, mutect2, varscan2
- DDX54 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1210402204, COSV58372447; called by muse, mutect2, varscan2
- DGKI | c.511-1G>A p.X171_splice | Splice Site (SNP) | VAF 63/293 reads (22%) | catalogued as COSV99935739; called by muse, mutect2, varscan2
- DNAH2 | c.10291G>C p.A3431P | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66718020; called by muse, mutect2, varscan2
- DTX3 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1254397402, COSV54087057; called by muse, mutect2, varscan2
- ELMOD1 | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99760554; called by muse, mutect2, varscan2
- EPHA10 | c.12C>G p.C4W | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.419); catalogued as COSV60406283; called by muse, mutect2, varscan2
- ERVV-2 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs989105714; called by muse, mutect2
- FAM47C | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.106); catalogued as rs377326539, COSV100792323, COSV63724457; called by muse, mutect2, varscan2
- FCRL5 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as COSV62516784; called by muse, mutect2
- FMO1 | c.916G>T p.V306L | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV61446358; called by muse, mutect2, varscan2
- GOLGA8J | c.1508C>A p.A503D | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs1489208897; called by mutect2, varscan2
- GRIN2C | c.1799G>A p.G600D | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165199543; called by muse, mutect2, varscan2
- IGHV4-59 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 90/607 reads (15%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as rs536223053; called by muse, mutect2, varscan2
- IHH | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs1559178825, COSV55392917; called by muse, mutect2, varscan2
- IL18R1 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs769222530; called by muse, mutect2, varscan2
- IRF2BP2 | c.1616A>C p.K539T | Missense Mutation (SNP) | VAF 66/365 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100784341; called by muse, mutect2, varscan2
- KCNA4 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV100068955, COSV60252205; called by muse, mutect2, varscan2
- KCND2 | c.752C>A p.A251E | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100474139, COSV58584879; called by muse, mutect2, varscan2
- KCNQ4 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308296992, COSV100714427; called by muse, mutect2, varscan2
- KIF14 | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 72/465 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs373895990, COSV66259940; called by muse, mutect2, varscan2
- KRTAP11-1 | c.447G>T p.R149S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as COSV60094403; called by muse, mutect2
- KRTAP13-1 | c.157T>C p.Y53H | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as rs149327725; called by muse, mutect2, varscan2
- KRTAP26-1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as rs1359002835; called by muse, mutect2, varscan2
- LDB3 | c.178A>T p.M60L | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs747835472; called by muse, mutect2, varscan2
- LPIN3 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs905101589, COSV64718285; called by muse, varscan2
- LRCH2 | c.1178G>A p.S393N | Missense Mutation (SNP) | VAF 97/175 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV104395611; called by muse, mutect2, varscan2
- LRFN5 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53264242; called by muse, mutect2, varscan2
- LRRC4C | c.1197C>A p.Y399* | Nonsense Mutation (SNP) | VAF 40/260 reads (15%) | catalogued as COSV53425412; called by muse, mutect2, varscan2
- LRRTM3 | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 62/357 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100791592; called by muse, mutect2, varscan2
- MKX | c.619C>G p.R207G | Missense Mutation (SNP) | VAF 67/353 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs752902262, COSV65391653; called by muse, mutect2, varscan2
- MLC1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.154); catalogued as COSV61117463; called by muse, mutect2, varscan2
- MORC1 | c.2602C>A p.Q868K | Missense Mutation (SNP) | VAF 91/386 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs753247879; called by muse, mutect2, varscan2
- MYOM2 | c.3991C>T p.Q1331* | Nonsense Mutation (SNP) | VAF 21/131 reads (16%) | catalogued as COSV100036434, COSV50791972; called by muse, varscan2
- NSUN2 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1326921792; called by muse, mutect2, varscan2
- NUDT19 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67959505; called by muse, mutect2, varscan2
- OLFM4 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99524246; called by muse, mutect2, varscan2
- OR14A16 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs1175425880; called by muse, mutect2, varscan2
- OR2A12 | c.810G>T p.R270S | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV68821160; called by muse, mutect2, varscan2
- OR2F1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV67331660, COSV67331693; called by muse, varscan2
- OR2L2 | c.895del p.A299Pfs*2 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | catalogued as COSV100824225, COSV63561835; called by mutect2, pindel
- OR4C15 | c.875C>A p.T292N (on ENST00000314644; = p.T238N on NM_001001920.2) | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs760598418, COSV100115582; called by muse, mutect2
- OR8D2 | c.638C>A p.A213E | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV62488141; called by muse, mutect2, varscan2
- OTOF | c.3337G>A p.D1113N (on ENST00000272371 / NM_194248.3; = p.D366N on NM_004802.4) | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as rs779794812; called by muse, mutect2, varscan2
- PDE3A | c.3282del p.Q1094Hfs*6 | Frame Shift Del (DEL) | VAF 85/476 reads (18%) | catalogued as COSV62969633; called by mutect2, pindel, varscan2
- PELI3 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs765259249; called by muse, mutect2, varscan2
- PER3 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs750771308; called by muse, mutect2, varscan2
- PHETA1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs201171784, COSV100825303; called by muse, mutect2, varscan2
- PLP1 | c.152T>A p.F51Y | Missense Mutation (SNP) | VAF 167/304 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as CM002823; called by muse, mutect2, varscan2
- POTEE | c.2425C>A p.P809T | Missense Mutation (SNP) | VAF 102/446 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs749101600; called by mutect2, varscan2
- POTEJ | c.2605C>T p.R869W | Missense Mutation (SNP) | VAF 72/600 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.98); catalogued as rs753778996; called by muse, varscan2
- PPIG | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 57/350 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV53644894; called by muse, mutect2, varscan2
- PTPRB | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV54248838, COSV54253544; called by muse, mutect2, varscan2
- RDH8 | c.571A>G p.I191V (on ENST00000651512; = p.I171V on NM_015725.4) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs778989348; called by muse, mutect2, varscan2
- RYR2 | c.4499G>A p.R1500H | Missense Mutation (SNP) | VAF 64/384 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs749719028, COSV63657232; called by muse, varscan2
- SKI | c.1229G>A p.S410N | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.867); catalogued as COSV101049587; called by muse, mutect2, varscan2
- SLC17A6 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); catalogued as rs773836933, COSV54136869; called by muse, mutect2, varscan2
- SOGA3 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs756112635; called by muse, mutect2, varscan2
- STAB2 | c.2508C>A p.F836L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs778614755, COSV101185987; called by muse, mutect2, varscan2
- TCERG1L | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV64059209; called by muse, mutect2, varscan2
- TGFB1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as rs779534698; called by muse, mutect2, varscan2
- TGFBR1 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 69/393 reads (18%) | catalogued as COSV66625502; called by muse, mutect2, varscan2
- TMEM132D | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV67161442; called by muse, mutect2, varscan2
- TNR | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV54884015; called by muse, mutect2, varscan2
- TP53 | c.268_269del p.S90Lfs*58 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | catalogued as COSV52885947; called by mutect2, pindel, varscan2
- TRHDE | c.1972A>G p.I658V | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1194435039; called by muse, mutect2, varscan2
- TRIM62 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1194127450; called by muse, mutect2, varscan2
- UNC80 | c.9563A>G p.Q3188R | Missense Mutation (SNP) | VAF 83/392 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs755648237; called by muse, mutect2, varscan2
- USH2A | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.767); catalogued as COSV56393365; called by muse, mutect2, varscan2
- UTP20 | c.3340G>T p.A1114S | Missense Mutation (SNP) | VAF 66/315 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55371866; called by muse, mutect2, varscan2
- VPS11 | c.388G>C p.D130H (on ENST00000620429; = p.D674H on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs782277549, COSV56186717; called by muse, mutect2, varscan2
- WDR4 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1353500983; called by muse, mutect2, varscan2
- ZHX2 | c.2039G>A p.R680K | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58716573; called by mutect2, varscan2
- ZNF180 | c.1195del p.H399Ifs*246 | Frame Shift Del (DEL) | VAF 73/218 reads (33%) | catalogued as COSV55420458, COSV99659952; called by mutect2, pindel, varscan2
- ZNF37A | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 56/307 reads (18%) | catalogued as COSV61072595; called by muse, mutect2, varscan2
- ZNF382 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV53090041; called by muse, mutect2, varscan2
- ZNF587B | c.1139G>A p.W380* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as rs1184994224; called by muse, mutect2, varscan2
- ZNF77 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs768214682, COSV58821904; called by mutect2, varscan2
- ZNF781 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs772286028, COSV62201701; called by muse, mutect2, varscan2
- ZNF91 | c.1838G>A p.W613* | Nonsense Mutation (SNP) | VAF 41/231 reads (18%) | catalogued as rs1394629357; called by muse, mutect2, varscan2
- ABTB1 | c.530G>T p.R177L (on ENST00000232744 / NM_172027.3; = p.R35L on NM_032548.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ACSBG1 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTA1 | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AEBP2 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- AKAP9 | c.5275G>T p.A1759S (on ENST00000359028; = p.A1727S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/386 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- AMOTL2 | c.1143C>A p.D381E | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKFN1 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD11 | c.3318G>T p.K1106N | Missense Mutation (SNP) | VAF 136/587 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ANKRD30B | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 49/326 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- ANKRD30B | c.2957A>G p.K986R | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ARL16 | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATP5F1B | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ATP5F1B | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- ATP6V1H | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- AUTS2 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- BORA | c.655A>T p.T219S (on ENST00000613797; = p.T144S on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.03); called by muse, varscan2
- C15orf48 | c.135A>C p.K45N | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.265); called by mutect2, varscan2
- C19orf44 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- C3orf18 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CAMSAP3 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDC42BPB | c.3416C>G p.P1139R | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CDH23 | c.2327C>A p.P776H | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEACAM18 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CEP83 | c.703A>G p.K235E | Missense Mutation (SNP) | VAF 81/475 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CHRNA3 | c.411del p.A139Pfs*9 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- CLEC4A | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CNGA2 | c.1868dup p.A625Gfs*21 | Frame Shift Ins (INS) | VAF 44/106 reads (42%) | called by mutect2, pindel, varscan2
- COL24A1 | c.3134T>A p.L1045* | Nonsense Mutation (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- COL6A3 | c.5156C>G p.T1719S | Missense Mutation (SNP) | VAF 85/414 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CPEB3 | c.1165G>T p.G389* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | called by muse, varscan2
- CR1 | c.3524C>T p.P1175L | Missense Mutation (SNP) | VAF 21/488 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, mutect2
- CTNND2 | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 130/457 reads (28%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CYYR1 | c.251T>C p.I84T | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- DAAM2 | c.2081A>C p.E694A | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DECR1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 102/356 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNAJC10 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOC2A | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- DPP4 | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DUOXA2 | c.770-3C>G | Splice Region (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- DYSF | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- EEF1D | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- EFCAB8 | c.1968C>G p.Y656* | Nonsense Mutation (SNP) | VAF 15/320 reads (5%) | called by muse, mutect2
- EFNA4 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ELK4 | c.1292_*2del | Nonstop Mutation (DEL) | VAF 34/173 reads (20%) | called by mutect2, pindel, varscan2
- ENO3 | c.865+2T>C p.X289_splice | Splice Site (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- ERO1A | c.1298T>C p.F433S | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FBRSL1 | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- FBXO40 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCER1A | c.544C>A p.Q182K | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FPR2 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- FRG2B | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 43/316 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- FSIP2 | c.8809C>T p.P2937S | Missense Mutation (SNP) | VAF 96/452 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- GASK1B | c.546G>T p.L182F | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- GJD2 | c.772T>A p.F258I | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GON4L | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- GSDMC | c.568A>T p.K190* | Nonsense Mutation (SNP) | VAF 70/485 reads (14%) | called by muse, mutect2, varscan2
- H2AC16 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- HABP2 | c.740+1G>A p.X247_splice | Splice Site (SNP) | VAF 22/104 reads (21%) | called by muse, varscan2
- HEPHL1 | c.550T>C p.W184R | Missense Mutation (SNP) | VAF 90/522 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- HERC2 | c.9537T>G p.D3179E | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIVEP1 | c.3932G>T p.S1311I | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IARS1 | c.2843T>A p.M948K | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCP | c.4037C>T p.A1346V (on ENST00000620378; = p.A1470V on NM_001366122.1) | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- KIF11 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 121/630 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KRTAP25-1 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, varscan2
- LCN6 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LGR6 | c.428+7C>T | Splice Region (SNP) | VAF 33/165 reads (20%) | called by muse, mutect2, varscan2
- LILRB5 | c.1669C>A p.Q557K (on ENST00000449561 / NM_001081442.3; = p.Q556K on NM_006840.5) | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- LINS1 | c.1907A>T p.D636V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- MCOLN3 | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 113/422 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- MDGA2 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, varscan2
- MMD | c.250T>C p.W84R | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MORC1 | c.2347G>T p.D783Y | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- MPDU1 | c.508-8T>A | Splice Region (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- MPEG1 | c.1350A>T p.E450D | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- MRTFA | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MTCL1 | c.1704G>C p.K568N (on ENST00000306329 / NM_001378206.1; = p.K208N on NM_015210.4) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH13 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYOCD | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NHS | c.2810A>C p.D937A | Missense Mutation (SNP) | VAF 154/442 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP5 | c.2642C>A p.A881D | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- NOTCH1 | c.3938del p.G1313Afs*132 | Frame Shift Del (DEL) | VAF 36/140 reads (26%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.4609G>A p.D1537N | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- NPR2 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NRIP1 | c.3168A>T p.K1056N | Missense Mutation (SNP) | VAF 70/420 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- OBP2A | c.389-5T>G | Splice Region (SNP) | VAF 14/64 reads (22%) | called by mutect2, varscan2
- OR10C1 | c.257T>C p.L86P (on ENST00000622521; = p.L84P on NM_013941.3) | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- OR2M7 | c.161A>G p.Q54R | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2T3 | c.263T>A p.V88E | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- OR2Z1 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- OR4C16 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PAQR7 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PARP1 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 75/509 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHB16 | c.1323A>G p.I441M | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- PCLO | c.1523A>T p.K508I | Missense Mutation (SNP) | VAF 66/494 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2
- PDE4DIP | c.5737A>G p.R1913G | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP2R1B | c.992A>G p.E331G | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PRCC | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PSAPL1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PSEN2 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PSMB11 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PTPN21 | c.404G>C p.C135S | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PXDNL | c.1861G>T p.V621F | Missense Mutation (SNP) | VAF 62/547 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- QPRT | c.376dup p.R126Kfs*48 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- RAD18 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- RASA1 | c.539+6T>C | Splice Region (SNP) | VAF 91/425 reads (21%) | called by muse, mutect2, varscan2
- RIMS2 | c.1426A>T p.T476S (on ENST00000666250 / NM_001348490.2; = p.T284S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/801 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- RPF1 | c.274del p.G93Afs*24 | Frame Shift Del (DEL) | VAF 39/240 reads (16%) | called by mutect2, pindel, varscan2
- RPL22 | c.243G>A p.R81= | Splice Region (SNP) | VAF 47/250 reads (19%) | called by muse, mutect2, varscan2
- SCCPDH | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCN1B | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 134/220 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SCN9A | c.4027T>C p.F1343L (on ENST00000303354; = p.F1332L on NM_002977.3) | Missense Mutation (SNP) | VAF 65/430 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SEC24B | c.1592G>A p.R531K | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SEPTIN3 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SH3GL1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC1 | c.2546G>C p.R849P | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SIPA1L1 | c.2836del p.S946Qfs*9 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- SLC17A3 | c.254T>A p.V85D | Missense Mutation (SNP) | VAF 87/416 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A5 | c.1139C>G p.P380R | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- SLC6A4 | c.456del p.I154Sfs*108 | Frame Shift Del (DEL) | VAF 34/166 reads (20%) | called by mutect2, pindel, varscan2
- SNX15 | c.73T>A p.Y25N | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SPEM2 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SPRY2 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- SPTA1 | c.1754A>G p.Q585R | Missense Mutation (SNP) | VAF 136/734 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STARD10 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- STS | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 152/397 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNGR2 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 64/291 reads (22%) | called by muse, mutect2, varscan2
- TBX20 | c.723dup p.S242Lfs*8 | Frame Shift Ins (INS) | VAF 74/325 reads (23%) | called by mutect2, pindel, varscan2
- TEX26 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM108 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMPRSS11F | c.477G>T p.L159F | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRANK1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TREH | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 29/114 reads (25%) | called by muse, mutect2, varscan2
- TRPC4 | c.1286A>T p.Y429F | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC7A | c.818C>A p.T273N | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TTN | c.61504G>A p.D20502N (on ENST00000591111; = p.D13078N on NM_003319.4) | Missense Mutation (SNP) | VAF 112/626 reads (18%) | PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- TTN | c.48185C>A p.T16062K (on ENST00000591111; = p.T8638K on NM_003319.4) | Missense Mutation (SNP) | VAF 120/670 reads (18%) | PolyPhen benign (0.385); called by muse, mutect2, varscan2
- TTN | c.16390G>T p.E5464* (on ENST00000591111; = p.E4537* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 83/515 reads (16%) | called by muse, mutect2, varscan2
- TXK | c.486T>G p.H162Q | Missense Mutation (SNP) | VAF 83/371 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- USP33 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VDR | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- VPS13B | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 105/314 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS45 | c.1502A>G p.D501G | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, varscan2
- VPS8 | c.818T>A p.F273Y (on ENST00000625842 / NM_001349294.1; = p.F271Y on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- WDR49 | c.1845A>T p.L615F (on ENST00000308378 / NM_001366158.1; = p.L956F on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/455 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XAGE3 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ZFHX4 | c.3554G>A p.G1185E | Missense Mutation (SNP) | VAF 107/303 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZFR | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 79/312 reads (25%) | called by muse, mutect2, varscan2
- ZNF235 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 62/153 reads (41%) | called by muse, mutect2, varscan2
- ZNF354B | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF667 | c.1270T>C p.F424L | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ZNF682 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF76 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF780B | c.2010A>T p.E670D | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ZNF804A | c.1752G>C p.E584D | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804A | c.2938C>A p.P980T | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ZNF831 | c.1823del p.G608Afs*5 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- ABCD4 | c.744G>A p.R248= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- AHNAK | c.12234A>G p.P4078= | Silent (SNP) | VAF 74/387 reads (19%) | called by muse, mutect2, varscan2
- ANK1 | c.3876C>T p.S1292= | Silent (SNP) | VAF 75/419 reads (18%) | called by muse, mutect2, varscan2
- ARCN1 | c.177G>A p.Q59= | Silent (SNP) | VAF 57/317 reads (18%) | called by muse, mutect2, varscan2
- ARSG | c.729C>G p.L243= | Silent (SNP) | VAF 24/212 reads (11%) | called by muse, mutect2
- ASIC3 | c.393G>A p.R131= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs1276775101; called by muse, mutect2, varscan2
- C7 | c.1524T>C p.S508= | Silent (SNP) | VAF 69/279 reads (25%) | called by muse, mutect2, varscan2
- CACNA1A | c.2787C>T p.A929= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- CCT8L2 | c.177C>T p.F59= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV63461727; called by muse, mutect2, varscan2
- CDC73 | c.102G>A p.K34= | Silent (SNP) | VAF 55/312 reads (18%) | catalogued as rs570083294, COSV66464897; called by muse, mutect2, varscan2
- CDH19 | c.561C>G p.L187= | Silent (SNP) | VAF 68/438 reads (16%) | called by muse, mutect2, varscan2
- CNBD1 | c.468G>T p.V156= | Silent (SNP) | VAF 29/195 reads (15%) | catalogued as COSV101575280; called by muse, mutect2, varscan2
- CTIF | c.102G>A p.E34= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- DYSF | c.5403C>T p.F1801= | Silent (SNP) | VAF 35/157 reads (22%) | called by muse, mutect2, varscan2
- ENO3 | c.78G>T p.T26= | Silent (SNP) | VAF 61/299 reads (20%) | called by muse, mutect2, varscan2
- ENPP7 | c.432C>A p.G144= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1167142924, COSV60385814; called by muse, mutect2, varscan2
- FAM110B | c.1065A>G p.L355= | Silent (SNP) | VAF 30/222 reads (14%) | called by mutect2, varscan2
- FBLIM1 | c.165C>A p.G55= | Silent (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- FUBP1 | c.1350A>G p.P450= | Silent (SNP) | VAF 27/186 reads (15%) | catalogued as rs765463248; called by muse, mutect2, varscan2
- GABRG1 | c.681G>C p.V227= | Silent (SNP) | VAF 43/328 reads (13%) | called by muse, mutect2, varscan2
- GIMAP6 | c.261T>A p.A87= | Silent (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- GJD2 | c.639C>T p.F213= | Silent (SNP) | VAF 65/317 reads (21%) | catalogued as rs896854275; called by muse, mutect2, varscan2
- GON4L | c.4926A>G p.L1642= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs1403453077; called by muse, mutect2, varscan2
- HDGF | c.27G>A p.E9= | Silent (SNP) | VAF 35/185 reads (19%) | called by muse, mutect2, varscan2
- HERC2 | c.12000G>T p.V4000= | Silent (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- HERC2 | c.5757G>A p.G1919= | Silent (SNP) | VAF 67/402 reads (17%) | catalogued as rs1238409369; called by muse, mutect2, varscan2
- INO80D | c.690C>T p.C230= | Silent (SNP) | VAF 12/296 reads (4%) | called by muse, mutect2
- KCNQ4 | c.1923G>A p.S641= | Silent (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- LIG1 | c.1194G>A p.P398= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as rs749379097; called by muse, mutect2, varscan2
- LRP2 | c.660G>C p.P220= | Silent (SNP) | VAF 81/535 reads (15%) | catalogued as COSV55578018; called by muse, mutect2, varscan2
- LRRTM3 | c.1584C>A p.P528= | Silent (SNP) | VAF 62/360 reads (17%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2250C>G p.S750= | Silent (SNP) | VAF 50/96 reads (52%) | called by muse, mutect2, varscan2
- MID2 | c.453A>G p.V151= | Silent (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- MSH2 | c.1419A>G p.S473= | Silent (SNP) | VAF 84/470 reads (18%) | catalogued as rs746674539; called by muse, mutect2, varscan2
- MTMR11 | c.2013A>G p.K671= (on ENST00000439741 / NM_001145862.2; = p.K599= on NM_181873.3) | Silent (SNP) | VAF 40/248 reads (16%) | called by muse, mutect2, varscan2
- MTMR14 | c.1098C>A p.L366= | Silent (SNP) | VAF 75/288 reads (26%) | called by muse, mutect2, varscan2
- MUC16 | c.41394C>A p.T13798= | Silent (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- MYO1G | c.1914C>T p.F638= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs144708261; called by muse, mutect2, varscan2
- NECTIN3 | c.1404C>T p.D468= | Silent (SNP) | VAF 47/235 reads (20%) | called by muse, varscan2
- NPAP1 | c.1932C>G p.T644= | Silent (SNP) | VAF 49/264 reads (19%) | called by muse, mutect2, varscan2
- NSMAF | c.423G>T p.G141= | Silent (SNP) | VAF 43/348 reads (12%) | catalogued as rs768990634; called by muse, mutect2, varscan2
- OR10K1 | c.849A>G p.P283= | Silent (SNP) | VAF 44/240 reads (18%) | catalogued as rs375044803; called by muse, mutect2, varscan2
- OR4X1 | c.363T>C p.Y121= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs1394898619; called by muse, mutect2, varscan2
- OR5M1 | c.99G>T p.A33= | Silent (SNP) | VAF 107/561 reads (19%) | catalogued as rs186105577; called by muse, mutect2, varscan2
- P2RY10 | c.954C>T p.R318= | Silent (SNP) | VAF 73/136 reads (54%) | called by muse, mutect2, varscan2
- PCLO | c.1521A>C p.T507= | Silent (SNP) | VAF 71/496 reads (14%) | called by muse, mutect2
- PGK2 | c.204T>C p.D68= | Silent (SNP) | VAF 44/233 reads (19%) | called by muse, mutect2, varscan2
- PKHD1 | c.2106G>T p.V702= | Silent (SNP) | VAF 84/425 reads (20%) | catalogued as COSV100582645; called by muse, mutect2, varscan2
- PLA2G1B | c.64C>A p.R22= | Silent (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- PLD2 | c.1377C>T p.D459= | Silent (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- PLOD2 | c.1377A>G p.P459= | Silent (SNP) | VAF 109/538 reads (20%) | called by muse, mutect2, varscan2
- PNLIP | c.627C>T p.D209= | Silent (SNP) | VAF 53/283 reads (19%) | catalogued as rs758874078; called by muse, mutect2, varscan2
- POLRMT | c.2338C>T p.L780= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs772344152; called by muse, varscan2
- POLRMT | c.2337G>T p.A779= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99241156; called by muse, mutect2, varscan2
- PPP1R3G | c.357C>A p.L119= | Silent (SNP) | VAF 11/41 reads (27%) | called by mutect2, varscan2
- PPP2R1B | c.111G>A p.V37= | Silent (SNP) | VAF 29/151 reads (19%) | called by muse, mutect2, varscan2
- RB1 | c.1386A>G p.K462= | Silent (SNP) | VAF 76/355 reads (21%) | called by muse, mutect2, varscan2
- ROBO2 | c.1836T>G p.P612= | Silent (SNP) | VAF 130/486 reads (27%) | called by muse, mutect2, varscan2
- RYR2 | c.2964C>T p.L988= | Silent (SNP) | VAF 39/314 reads (12%) | catalogued as rs202085370; called by muse, mutect2, varscan2
- SCD | c.711C>T p.F237= | Silent (SNP) | VAF 71/382 reads (19%) | called by muse, mutect2, varscan2
- SDHAF4 | c.48G>T p.T16= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as rs761014846; called by muse, mutect2, varscan2
- SLC16A6 | c.831C>T p.S277= | Silent (SNP) | VAF 32/211 reads (15%) | catalogued as rs370850876; called by muse, mutect2, varscan2
- SLC17A1 | c.564G>A p.V188= | Silent (SNP) | VAF 33/243 reads (14%) | called by muse, mutect2, varscan2
- SLC37A3 | c.1107G>A p.G369= | Silent (SNP) | VAF 45/299 reads (15%) | called by muse, mutect2, varscan2
- SLFN14 | c.2611C>T p.L871= | Silent (SNP) | VAF 90/539 reads (17%) | called by muse, mutect2, varscan2
- SLIT3 | c.3849C>A p.P1283= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- SNX29 | c.855A>T p.T285= | Silent (SNP) | VAF 68/258 reads (26%) | called by mutect2, varscan2
- SPON2 | c.609C>T p.A203= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ST14 | c.15G>A p.R5= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- ST3GAL6 | c.546G>A p.T182= | Silent (SNP) | VAF 44/269 reads (16%) | catalogued as rs747652874, COSV54580937; called by muse, mutect2, varscan2
- SUCLG1 | c.102G>T p.P34= | Silent (SNP) | VAF 41/255 reads (16%) | called by muse, mutect2, varscan2
- SUSD4 | c.1176C>T p.P392= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as rs760127054, COSV100663932; called by muse, mutect2, varscan2
- TMEM132D | c.1497G>A p.K499= | Silent (SNP) | VAF 33/172 reads (19%) | catalogued as COSV101242687; called by muse, mutect2, varscan2
- TMPRSS15 | c.2298G>A p.Q766= | Silent (SNP) | VAF 56/316 reads (18%) | called by muse, mutect2, varscan2
- TSPAN32 | c.414G>T p.T138= | Silent (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- TTC8 | c.1314G>T p.L438= (on ENST00000338104 / NM_001288781.1; = p.L422= on NM_144596.4) | Silent (SNP) | VAF 117/616 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.15846A>C p.A5282= (on ENST00000591111; = p.A4355= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/352 reads (19%) | called by muse, mutect2, varscan2
- UNC80 | c.2700C>T p.I900= | Silent (SNP) | VAF 43/267 reads (16%) | catalogued as rs995706379, COSV55899628; called by muse, mutect2, varscan2
- VTN | c.201G>A p.V67= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- WDR76 | c.1677A>G p.Q559= | Silent (SNP) | VAF 53/263 reads (20%) | catalogued as rs1342870253; called by muse, mutect2, varscan2
- XXYLT1 | c.1128G>A p.E376= | Silent (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- ZMYND11 | c.558G>T p.P186= | Silent (SNP) | VAF 43/256 reads (17%) | called by muse, mutect2, varscan2
- ZNF208 | c.2988T>A p.T996= | Silent (SNP) | VAF 66/369 reads (18%) | catalogued as COSV101236609; called by muse, mutect2, varscan2
- ZNF208 | c.123C>G p.V41= | Silent (SNP) | VAF 34/275 reads (12%) | called by muse, mutect2, varscan2
- AC025048.6 | n.239C>T | RNA (SNP) | VAF 74/290 reads (26%) | catalogued as rs1207762685; called by muse, mutect2, varscan2
- AC068631.2 | c.452-45A>T | Intron (SNP) | VAF 74/315 reads (23%) | called by muse, mutect2, varscan2
- AC073343.1 | n.500C>A | RNA (SNP) | VAF 64/225 reads (28%) | called by muse, mutect2, varscan2
- AC103993.1 | n.164T>A | RNA (SNP) | VAF 58/336 reads (17%) | called by muse, varscan2
- AC107023.1 | chr12:40445543 C>T | 5'Flank (SNP) | VAF 72/307 reads (23%) | catalogued as rs776662405; called by muse, mutect2, varscan2
- ACTN2 | c.1840-14T>A | Intron (SNP) | VAF 66/351 reads (19%) | called by muse, varscan2
- AGTR1 | c.-11A>T | 5'UTR (SNP) | VAF 53/330 reads (16%) | called by muse, mutect2, varscan2
- AL353753.1 | n.416A>G | RNA (SNP) | VAF 28/128 reads (22%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851340 C>T | 3'Flank (SNP) | VAF 63/165 reads (38%) | called by muse, mutect2, varscan2
- ALOXE3 | c.-313-63G>T | Intron (SNP) | VAF 38/261 reads (15%) | called by muse, mutect2, varscan2
- ALX1 | c.*16T>C | 3'UTR (SNP) | VAF 66/412 reads (16%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504715 A>G | 5'Flank (SNP) | VAF 66/349 reads (19%) | called by muse, mutect2, varscan2
- C8orf34 | c.327+32G>T | Intron (SNP) | VAF 36/240 reads (15%) | called by muse, mutect2
- C8orf34 | c.327+34C>T | Intron (SNP) | VAF 34/234 reads (15%) | called by muse, mutect2
- CCDC167 | c.-3A>T | 5'UTR (SNP) | VAF 20/119 reads (17%) | catalogued as rs762041543; called by muse, mutect2, varscan2
- CERS5 | c.197+1123C>T | Intron (SNP) | VAF 26/142 reads (18%) | called by muse, mutect2, varscan2
- CHODL | c.79+613G>A | Intron (SNP) | VAF 66/313 reads (21%) | called by muse, mutect2, varscan2
- CSF3R | c.2040+16G>A | Intron (SNP) | VAF 48/295 reads (16%) | called by muse, mutect2, varscan2
- CSH2 | c.10+21T>A | Intron (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
- CTNNA2 | c.102+35971C>T | Intron (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- DBT | chr1:100249861 C>T | 5'Flank (SNP) | VAF 41/201 reads (20%) | called by muse, mutect2, varscan2
- DCAF13 | c.270+32A>T | Intron (SNP) | VAF 53/443 reads (12%) | called by muse, mutect2, varscan2
- ELMO2 | c.119+14G>A | Intron (SNP) | VAF 48/285 reads (17%) | called by muse, mutect2, varscan2
- EYS | c.1766+2606A>G | Intron (SNP) | VAF 84/433 reads (19%) | called by muse, mutect2, varscan2
- FASTKD2 | c.*48_*52del | 3'UTR (DEL) | VAF 32/211 reads (15%) | called by mutect2, pindel, varscan2
- FRMD8P1 | n.661G>T | RNA (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- GBA2 | c.2506-74C>T | Intron (SNP) | VAF 65/285 reads (23%) | catalogued as rs898662253; called by muse, mutect2, varscan2
- HMG20B | c.*268G>T | 3'UTR (SNP) | VAF 21/125 reads (17%) | catalogued as rs746477044; called by muse, mutect2, varscan2
- KCTD8 | c.962-118188A>T | Intron (SNP) | VAF 54/394 reads (14%) | catalogued as COSV63590517; called by muse, mutect2, varscan2
- KDM5D | c.2583+237C>A | Intron (SNP) | VAF 87/210 reads (41%) | called by muse, mutect2, varscan2
- KHDRBS3 | c.88+909C>T | Intron (SNP) | VAF 95/292 reads (33%) | catalogued as rs1009544900; called by muse, mutect2, varscan2
- KIDINS220 | chr2:8726931 C>A | 3'Flank (SNP) | VAF 34/274 reads (12%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-5854C>G | Intron (SNP) | VAF 37/168 reads (22%) | called by muse, mutect2, varscan2
- LINC00479 | n.334G>A | RNA (SNP) | VAF 21/103 reads (20%) | catalogued as rs533515139; called by muse, mutect2, varscan2
- LINC01169 | n.360del | RNA (DEL) | VAF 23/206 reads (11%) | called by mutect2, pindel, varscan2
- MIR513B | n.49T>C | RNA (SNP) | VAF 75/180 reads (42%) | called by muse, mutect2, varscan2
- MOV10L1 | c.97+286T>C | Intron (SNP) | VAF 33/149 reads (22%) | called by muse, mutect2, varscan2
- NECTIN3 | c.160+2050G>C | Intron (SNP) | VAF 35/192 reads (18%) | called by muse, mutect2, varscan2
- NLRX1 | c.*304C>T | 3'UTR (SNP) | VAF 60/285 reads (21%) | called by muse, mutect2, varscan2
- PAX3 | c.*15T>C | 3'UTR (SNP) | VAF 50/291 reads (17%) | catalogued as rs900977338; called by muse, mutect2, varscan2
- PLEC | c.523+4970C>T | Intron (SNP) | VAF 14/73 reads (19%) | catalogued as rs782734530; called by muse, mutect2, varscan2
- PLEKHM1P1 | n.1135A>G | RNA (SNP) | VAF 16/77 reads (21%) | catalogued as rs1480823244; called by muse, mutect2, varscan2
- RAB40B | c.*155C>T | 3'UTR (SNP) | VAF 36/110 reads (33%) | catalogued as rs759119048; called by muse, mutect2
- REXO1L1P | n.754G>A | RNA (SNP) | VAF 17/246 reads (7%) | catalogued as rs1490696941; called by muse, mutect2
- RNA5-8SP2 | chr16:34159153 C>A | 5'Flank (SNP) | VAF 21/93 reads (23%) | catalogued as rs754741623; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559509 G>A | 5'Flank (SNP) | VAF 66/446 reads (15%) | called by muse, mutect2, varscan2
- ROBO3 | c.*43G>T | 3'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- ROBO3 | c.*44G>T | 3'UTR (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- ROPN1 | c.116+869G>C | Intron (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- RPL14 | c.-1C>A | 5'UTR (SNP) | VAF 10/64 reads (16%) | catalogued as rs200788022, COSV100166249; called by muse, mutect2, varscan2
- SERPING1 | c.1029+227A>G | Intron (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- SLC12A4 | c.1630-10G>A | Intron (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- SLC6A10P | n.2958C>G | RNA (SNP) | VAF 41/227 reads (18%) | called by muse, mutect2, varscan2
- SLF2 | c.3486+23C>T | Intron (SNP) | VAF 31/190 reads (16%) | catalogued as rs773430502; called by muse, mutect2, varscan2
- SNORD116-13 | n.33T>C | RNA (SNP) | VAF 26/169 reads (15%) | called by muse, mutect2, varscan2
- SSPOP | n.10430A>G | RNA (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- TBC1D4 | c.-40G>T | 5'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as rs904769718; called by muse, mutect2
- TBCE | c.372-3507C>T | Intron (SNP) | VAF 58/456 reads (13%) | called by muse, mutect2, varscan2
- TRPA1 | c.1530-32T>C | Intron (SNP) | VAF 52/370 reads (14%) | called by muse, mutect2, varscan2
- TTYH1 | chr19:54415261 G>A | 5'Flank (SNP) | VAF 66/149 reads (44%) | catalogued as rs1375795919; called by muse, mutect2, varscan2
- ZIC4 | c.688+1941G>C | Intron (SNP) | VAF 37/224 reads (17%) | called by muse, mutect2, varscan2
